Gene-level copy-number profile of tumor specimen C3L-02707-71 (profiled together with C3L-02707-72, C3L-02707-75) from CPTAC case C3L-02707, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.2 years (21,250 days).
Specimen C3L-02707-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c7399333-587b-4027-8656-7db2e8eae464.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02707-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/ebc3c617-70c0-4e9f-8423-8ff0e3e80b4d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 179; copy number 2: 5,646; copy number 3: 1,047; copy number 4: 44,411; copy number 5: 571; copy number 6: 6,731; copy number 9: 87; copy number 10: 4; copy number 14: 39; copy number 15: 11; copy number 16: 3; copy number 17: 10; copy number 20: 4; copy number 23: 8; copy number 24: 11; copy number 25: 21; copy number 26: 2; copy number 27: 2; copy number 55: 29; copy number 84: 4; copy number 88: 1; copy number 102: 9; copy number 106: 2; copy number 108: 7; copy number 111: 1; copy number 122: 4; copy number 133: 2; copy number 138: 5; copy number 140: 23; copy number 177: 5; copy number 181: 6; copy number 230: 13; copy number 233: 4.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:83,067,962–84,140,582, 9 genes (within-gene range 0–2): RNU6-478P, MARK2P15, LINC02650, AC069540.1, RNU6-129P, AL390786.1, RNU1-65P, HMGN2P8, AL603756.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 317 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:35,638,945–35,794,496, 1 gene, copy number 233 (within-gene range 5–233): ARPP21.
- chr3:35,744,476–36,170,448, 3 genes, copy number 233: MIR128-2, AC104308.1, RFC3P1.
- chr4:52,862,317–54,976,371, 32 genes, copy number 55–106: RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3.
- chr7:54,542,325–55,260,256, 13 genes, copy number 230: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:137,227,341–141,480,380, 87 genes, copy number 9 (broad region; genes not listed).
- chr10:48,040,462–48,040,577, 1 gene, copy number 20: RNA5SP315.
- chr12:57,253,762–57,431,005, 2 genes, copy number 27 (within-gene range 2–27): R3HDM2, RNU6-879P.
- chr12:57,434,784–59,789,855, 67 genes, copy number 23–140 (broad region; genes not listed).
- chr12:66,950,754–72,670,758, 108 genes, copy number 10–181 (within-gene range 2–181) (broad region; genes not listed).
- chr12:73,115,957–73,208,317, 3 genes, copy number 20: AC090503.2, LINC02444, AC090503.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
